Somatic mutation profile of tumor specimen TARGET-30-PAPTLA-01A (aliquot TARGET-30-PAPTLA-01A-01D) from TARGET case TARGET-30-PAPTLA, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.0 years (1,089 days).
Specimen TARGET-30-PAPTLA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 080a36af-3ace-4701-ab45-2c5d728bddb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPTLA-10A (Blood Derived Normal), aliquot TARGET-30-PAPTLA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e340d63f-71e8-44eb-aa81-8f8789b1beca

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.6951G>T p.E2317D | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753657019, COSV67987916; called by mutect2, varscan2
- ALG13 | c.2300G>C p.G767A | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52640576; called by muse, mutect2, varscan2
- ALG5 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.029); catalogued as COSV53505917; called by muse, mutect2, varscan2
- AOC3 | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53827397; called by muse, mutect2, varscan2
- DDX54 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 60/116 reads (52%) | catalogued as COSV58374364; called by mutect2, varscan2
- NLGN1 | c.856A>G p.K286E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.045); catalogued as COSV64337415; called by muse, mutect2
- PLA2R1 | c.2689C>G p.Q897E | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.856); catalogued as COSV51780926; called by muse, mutect2, varscan2
- PPP2R5B | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV51210687; called by mutect2, varscan2
- PRDM2 | c.980C>A p.S327* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as COSV52449262; called by mutect2, varscan2
- RFX2 | c.1840C>A p.L614M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV57942518; called by mutect2, varscan2
- RHBDF1 | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV51956175; called by muse, mutect2, varscan2
- SEC16A | c.1342G>T p.V448L | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51530613; called by muse, mutect2, varscan2
- SLFN5 | c.1805A>T p.E602V | Missense Mutation (SNP) | VAF 73/378 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV55481731; called by muse, mutect2, varscan2
- ZIC4 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as rs773811220, COSV101268028, COSV67172402; called by muse, varscan2
- ADGRF5 | c.317del p.N106Mfs*2 | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | called by mutect2, pindel, varscan2
- CCDC7 | c.3063del p.N1021Kfs*16 | Frame Shift Del (DEL) | VAF 42/187 reads (22%) | called by mutect2, pindel, varscan2
- ITSN2 | c.691_694del p.P231Rfs*15 | Frame Shift Del (DEL) | VAF 26/124 reads (21%) | called by mutect2, pindel, varscan2
- MON2 | c.3181C>T p.H1061Y | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.18); called by mutect2, varscan2
- NIPBL | c.3157_3159delinsACCG p.P1053Tfs*8 | Frame Shift Ins (INS) | VAF 30/147 reads (20%) | called by pindel, varscan2*
- DUSP22 | c.450G>C p.L150= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as COSV60528110; called by muse, mutect2, varscan2
- IGHV3-53 | c.321G>A p.E107= | Silent (SNP) | VAF 136/188 reads (72%) | catalogued as rs1555544968; called by muse, varscan2
- MON2 | c.3180G>A p.Q1060= | Silent (SNP) | VAF 38/151 reads (25%) | called by muse, mutect2, varscan2
- MTUS2 | c.2385C>T p.S795= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs749268070, COSV70915839, COSV70917454; called by mutect2, varscan2
- RNU6-104P | chr8:43300534 T>C | 5'Flank (SNP) | VAF 50/141 reads (35%) | catalogued as rs1201198518; called by muse, mutect2, varscan2
